Somatic mutation profile of tumor specimen TCGA-BT-A20N-01A (aliquot TCGA-BT-A20N-01A-11D-A14W-08) from TCGA case TCGA-BT-A20N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.4 years (26,456 days).
Specimen TCGA-BT-A20N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f98b0f76-a7e5-4ba0-a429-3ffbf6cac505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20N-11A (Solid Tissue Normal), aliquot TCGA-BT-A20N-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aed3dcb1-9f29-49ae-b6a6-1a3633bf7878

The open-access MAF lists 289 somatic variants for this specimen: 207 protein-altering or splice-affecting, 78 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 78, Nonsense Mutation 14, Frame Shift Del 7, Splice Site 3, Frame Shift Ins 3, 5'Flank 3, In Frame Del 2, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.831T>A p.C277* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | hotspot (GDC flag); catalogued as rs1057523347, CM065496, COSV52676368, COSV52783531, COSV53164903; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCC3 | c.3920G>C p.R1307T | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV53327807; called by muse, mutect2, varscan2
- ACTRT3 | c.597G>C p.L199F | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.614); catalogued as COSV57755169, COSV99042866; called by muse, mutect2
- ADAM9 | c.2227C>G p.Q743E | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65961235, COSV65961845; called by muse, mutect2
- ADAMTS6 | c.811A>C p.I271L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV66863814; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4574G>C p.R1525T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV54471181; called by muse, mutect2
- AFF1 | c.2203C>G p.R735G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV57123209; called by muse, mutect2, varscan2
- AFP | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV56926728; called by muse, mutect2, varscan2
- AHNAK | c.16811C>G p.S5604C | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs778888353, COSV57223628, COSV57226622; called by muse, mutect2, varscan2
- AMIGO1 | c.636C>G p.I212M | Missense Mutation (SNP) | VAF 59/89 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV63990568; called by muse, mutect2, varscan2
- AMOTL1 | c.2489G>T p.G830V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58569940; called by muse, mutect2
- ARPP21 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as rs554898023, COSV51801464; called by muse, mutect2, varscan2
- ARRDC3 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54366359; called by muse, mutect2, varscan2
- ASPM | c.4508C>T p.A1503V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV54136902; called by muse, mutect2, varscan2
- ASXL2 | c.3477G>C p.L1159F | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV55466307; called by muse, mutect2, varscan2
- ATP2B2 | c.1336G>C p.E446Q (on ENST00000352432; = p.E412Q on NM_001683.5) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59500616, COSV59505825; called by muse, varscan2
- BIRC6 | c.8267C>G p.P2756R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.345); catalogued as COSV70204458; called by muse, mutect2, varscan2
- BRDT | c.1820T>G p.L607R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV62866973; called by muse, mutect2, varscan2
- C16orf46 | c.228G>T p.R76S | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV55152733; called by muse, mutect2
- C1orf158 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55347268, COSV55347729; called by muse, mutect2, varscan2
- CACTIN | c.2091G>T p.E697D | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.817); catalogued as COSV50272287; called by muse, mutect2
- CCDC38 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV60184547; called by muse, mutect2, varscan2
- CCNB3 | c.4131G>T p.M1377I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV52078714; called by muse, mutect2, varscan2
- CCPG1 | c.1095dup p.H366Tfs*5 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | catalogued as rs749898304; called by mutect2, pindel, varscan2
- CD300A | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1179005813, COSV60410763; called by muse, mutect2, varscan2
- CD5L | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs773798853, COSV63821903, COSV63823426; called by muse, mutect2, varscan2
- CFAP45 | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV63650594; called by muse, mutect2
- CFAP46 | c.6961C>G p.P2321A | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs762394216, COSV54158365; called by muse, mutect2
- CFAP46 | c.6960G>T p.Q2320H | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs768156030, COSV54158382; called by muse, mutect2, varscan2
- CHRNB2 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63809248; called by muse, mutect2
- COL4A5 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs763882494, COSV60369705, COSV60375583; called by muse, varscan2
- COL4A6 | c.3487G>A p.G1163R | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV57875243; called by muse, mutect2, varscan2
- COL6A5 | c.6389A>T p.Y2130F (on ENST00000312481; = p.Y2126F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.494); catalogued as COSV99591383; called by muse, mutect2
- COPS4 | c.1008A>T p.E336D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52316897; called by muse, varscan2
- CRTAC1 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV54008434; called by muse, mutect2, varscan2
- CSRNP2 | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV57335146, COSV99950412; called by muse, mutect2
- CYP2A7 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52505637; called by muse, mutect2, varscan2
- DCHS1 | c.5313G>A p.M1771I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765375271, COSV55031940; called by muse, mutect2, varscan2
- DENND4A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV71266869; called by muse, mutect2, varscan2
- DIP2B | c.4479-1G>T p.X1493_splice | Splice Site (SNP) | VAF 47/95 reads (49%) | catalogued as COSV56590613; called by muse, mutect2, varscan2
- DMXL2 | c.5737A>G p.K1913E | Missense Mutation (SNP) | VAF 108/182 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as COSV51854273; called by muse, mutect2, varscan2
- DSCAM | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 16/172 reads (9%) | catalogued as COSV101261252; called by muse, mutect2
- ECM2 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.039); catalogued as COSV60742605; called by muse, mutect2, varscan2
- ECSIT | c.375C>G p.D125E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52940726; called by muse, mutect2
- EFCAB5 | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as COSV57935736; called by muse, mutect2
- EIF3I | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV59085295; called by muse, mutect2, varscan2
- EML1 | c.1105-1G>C p.X369_splice | Splice Site (SNP) | VAF 10/151 reads (7%) | catalogued as COSV51751374; called by muse, mutect2
- EPS15 | c.219C>G p.F73L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV65532528, COSV65532752; called by muse, mutect2, varscan2
- ETF1 | c.421T>G p.S141A | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62128002; called by muse, mutect2, varscan2
- FAM181A | c.46_47insA p.A16Dfs*53 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | catalogued as COSV50891148; called by mutect2, pindel*, varscan2
- FAM234A | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56997574; called by muse, mutect2, varscan2
- FAM71A | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as COSV54236962; called by muse, mutect2, varscan2
- FASTKD5 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53908826; called by muse, mutect2, varscan2
- FBXW11 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs1177616249, COSV51613076; called by muse, mutect2, varscan2
- FGA | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57399958; called by muse, mutect2, varscan2
- FGA | c.2233G>T p.G745C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57399972; called by muse, mutect2, varscan2
- FGFR4 | c.503T>A p.V168D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52808783; called by muse, mutect2, varscan2
- FLG | c.2143C>G p.Q715E | Missense Mutation (SNP) | VAF 531/926 reads (57%) | SIFT deleterious (0.02); catalogued as COSV64247304; called by muse, varscan2
- FLG2 | c.2789G>A p.S930N | Missense Mutation (SNP) | VAF 38/562 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV66172158; called by muse, mutect2
- FZD10 | c.763C>G p.R255G | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57475452; called by muse, mutect2, varscan2
- GARNL3 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59229646; called by muse, mutect2, varscan2
- GBA | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV59169902; called by muse, mutect2, varscan2
- GCN1 | c.7625C>G p.T2542R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as COSV56113645; called by muse, mutect2, varscan2
- GCN1 | c.1287C>G p.F429L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV56113652; called by muse, mutect2
- GPR141 | c.828C>G p.S276R | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57733092, COSV57733755; called by muse, mutect2
- HAS3 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54708836; called by muse, mutect2, varscan2
- HCN1 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 55/219 reads (25%) | catalogued as rs35229491, COSV100300654, COSV57498398; ClinVar: likely benign; called by muse, mutect2, varscan2
- HECW2 | c.3800T>C p.F1267S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53671707; called by muse, mutect2, varscan2
- HSPB2 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV57052386; called by muse, mutect2, varscan2
- INSRR | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63875004; called by muse, mutect2
- IREB2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV51926063; called by muse, mutect2, varscan2
- ITGAD | c.2657C>T p.T886I | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV66759775; called by muse, mutect2
- ITIH5 | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV53672404; called by muse, mutect2, varscan2
- ITIH5 | c.2452C>A p.P818T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV53672413; called by muse, mutect2, varscan2
- KCNJ16 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52256690; called by muse, mutect2, varscan2
- KCNJ6 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.243); catalogued as COSV55721097; called by muse, mutect2, varscan2
- KDM5A | c.3697C>T p.L1233F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66995709; called by muse, mutect2, varscan2
- KIF2C | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs865986322, COSV64768657; called by muse, mutect2, varscan2
- KLHL17 | c.1726G>T p.D576Y | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV58533232; called by muse, mutect2, varscan2
- KMT2A | c.8293G>C p.E2765Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.255); catalogued as COSV63291368; called by muse, mutect2
- KMT2D | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV99976177; called by muse, mutect2, varscan2
- KNG1 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53980546; called by muse, mutect2
- KRT76 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs749784108, COSV60120114, COSV60121237; called by muse, mutect2
- KRT79 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV57941919; called by muse, mutect2, varscan2
- KRTAP22-1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 35/136 reads (26%) | PolyPhen probably damaging (0.94); catalogued as rs754504713, COSV58182470; called by muse, mutect2, varscan2
- LDLRAP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV65474080; called by muse, mutect2, varscan2
- LMOD2 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311429937; called by muse, mutect2, varscan2
- LRIG3 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57868965; called by muse, mutect2, varscan2
- MASP1 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1264538703; called by muse, mutect2
- MASP2 | c.889+1G>A p.X297_splice | Splice Site (SNP) | VAF 30/133 reads (23%) | catalogued as COSV68897382; called by muse, mutect2, varscan2
- MATN2 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.111); catalogued as COSV54718117; called by muse, mutect2, varscan2
- MCCC2 | c.825C>A p.H275Q | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV60156502; called by muse, mutect2, varscan2
- MDN1 | c.16549C>T p.R5517W | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs764639892, COSV65520202, COSV65528740; called by muse, mutect2
- MECOM | c.69C>A p.C23* (on ENST00000468789 / NM_001105078.4; = p.C211* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 14/149 reads (9%) | catalogued as COSV52976360; called by muse, mutect2
- MED12L | c.4918A>G p.M1640V | Missense Mutation (SNP) | VAF 123/208 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs778502310, COSV56393618; called by muse, varscan2
- MEIS1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55491437; called by muse, mutect2, varscan2
- METTL25 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs141543492; called by muse, mutect2, varscan2
- MFN1 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54941981; called by muse, mutect2
- MOS | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61336004, COSV61336884; called by muse, mutect2, varscan2
- MTERF4 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769248754, COSV54090775; called by muse, mutect2
- MTMR11 | c.1186G>A p.E396K (on ENST00000439741 / NM_001145862.2; = p.E324K on NM_181873.3) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs781789146, COSV54966691; called by muse, mutect2, varscan2
- MYH13 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52840132; called by muse, mutect2, varscan2
- MYLK | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 149/324 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV60620014; called by muse, mutect2, varscan2
- NAA35 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV64486269; called by muse, mutect2
- NAV2 | c.2440C>T p.R814W (on ENST00000396087 / NM_001244963.2; = p.R791W on NM_145117.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773530667, COSV100585355, COSV62320948; called by muse, mutect2, varscan2
- NDC80 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs377218212; called by muse, mutect2, varscan2
- NEK11 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1351097984, COSV63583497; called by muse, mutect2, varscan2
- NIN | c.5670A>T p.K1890N (on ENST00000382041 / NM_182946.1; = p.K1177N on NM_016350.4) | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV55403577; called by muse, mutect2, varscan2
- NLRP4 | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as rs745985085, COSV56721531; called by muse, mutect2, varscan2
- NOSIP | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV59200102; called by muse, mutect2, varscan2
- NPAS3 | c.2078C>G p.S693C (on ENST00000356141 / NM_001164749.2; = p.S661C on NM_022123.3) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV60856786; called by muse, mutect2, varscan2
- NSMAF | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV50698499; called by muse, mutect2, varscan2
- NTRK1 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs200575096, CD013192, COSV62328120; ClinVar: uncertain significance; called by muse, mutect2
- NUAK2 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV65682498; called by muse, mutect2, varscan2
- OPCML | c.965A>T p.N322I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV59445121; called by muse, mutect2, varscan2
- OR10H4 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as COSV59062675, COSV59062790; called by muse, mutect2, varscan2
- OR56A4 | c.980T>G p.V327G | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV58111503; called by muse, mutect2, varscan2
- OR5K2 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV71143467; called by muse, mutect2, varscan2
- OR7A5 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV59235331; called by muse, mutect2, varscan2
- OR8B12 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60911113, COSV60912211; called by muse, mutect2, varscan2
- ORC3 | c.1164G>C p.L388F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57642999; called by muse, mutect2, varscan2
- OXR1 | c.884G>T p.G295V (on ENST00000442977 / NM_001198532.1; = p.G294V on NM_018002.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56335029; called by muse, mutect2, varscan2
- PAAF1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs761376744, COSV60156964; called by muse, mutect2, varscan2
- PHIP | c.5298G>C p.M1766I | Missense Mutation (SNP) | VAF 110/849 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); catalogued as COSV51509303; called by muse, mutect2, varscan2
- PKNOX2 | c.966G>T p.R322S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV53552833; called by muse, mutect2, varscan2
- POU5F1 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99462915; called by muse, mutect2, varscan2
- PPP2R2C | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV100160790, COSV59447144; called by mutect2, varscan2
- PRDM15 | c.3173C>A p.T1058N | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.326); catalogued as COSV54158583; called by muse, mutect2
- PRDM16 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54605329; called by muse, mutect2, varscan2
- PRKD1 | c.2258A>G p.E753G | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59582722; called by muse, mutect2, varscan2
- RAD54B | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1400780528, COSV60254205; called by muse, varscan2
- RAI14 | c.1996A>C p.K666Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.796); catalogued as COSV54302010; called by muse, mutect2
- RHCG | c.1018A>T p.I340F | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51518123; called by muse, mutect2, varscan2
- RHOB | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as COSV55357082; called by muse, mutect2, varscan2
- RIDA | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV54705468; called by muse, mutect2, varscan2
- RORB | c.328A>G p.K110E (on ENST00000396204 / NM_001365023.1; = p.K99E on NM_006914.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV65339287; called by muse, mutect2, varscan2
- SAP130 | c.414G>C p.E138D | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV52101630; called by muse, mutect2, varscan2
- SEL1L | c.2098G>T p.D700Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100377535, COSV60922148; called by muse, mutect2
- SELENOO | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373024917; called by muse, mutect2, varscan2
- SH3PXD2B | c.2435dup p.L812Ffs*6 | Frame Shift Ins (INS) | VAF 13/30 reads (43%) | catalogued as COSV100288348; called by mutect2, pindel, varscan2
- SIGIRR | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as COSV58987970; called by muse, mutect2, varscan2
- SLC12A4 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV57934334; called by muse, mutect2, varscan2
- SLC49A3 | c.1087G>C p.E363Q (on ENST00000404286 / NM_001294341.2; = p.E362Q on NM_032219.4) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59141567; called by muse, mutect2
- SMARCC1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV54385463; called by muse, mutect2, varscan2
- SNW1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs745391146, COSV53174855; called by muse, mutect2
- SPANXD | c.137A>G p.E46G | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV65152418; called by muse, mutect2
- SPEG | c.3902T>A p.L1301H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56678070; called by muse, mutect2, varscan2
- ST7L | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as COSV54146879; called by muse, mutect2
- ST7L | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.134); catalogued as rs763465036, COSV54145061, COSV54145312, COSV54146886; called by muse, mutect2, varscan2
- STAT1 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100738924, COSV63117239, COSV63117311; called by muse, mutect2, varscan2
- TAB1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs774694760, COSV53369980; called by muse, mutect2, varscan2
- TAGLN | c.104T>C p.I35T | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV54064146; called by muse, mutect2, varscan2
- TCHH | c.4143G>C p.Q1381H | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.333); catalogued as rs368649993, COSV64277280; called by muse, mutect2
- TEX15 | c.2345G>A p.R782K (on ENST00000256246; = p.R1165K on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56341209, COSV56352319; called by muse, mutect2
- TFAP2C | c.1250A>T p.K417I | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV52372855; called by muse, mutect2
- TGFBRAP1 | c.2455C>G p.Q819E | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV51515373; called by muse, mutect2, varscan2
- TGIF2LX | c.309T>A p.N103K | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV52214995; called by muse, mutect2, varscan2
- THAP9 | c.2681del p.L894Cfs*2 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as COSV56356051; called by mutect2, varscan2
- THUMPD1 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV67263462; called by muse, mutect2, varscan2
- TM9SF4 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.56); catalogued as COSV54110829; called by muse, mutect2, varscan2
- TMEM131L | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV53649546; called by muse, mutect2, varscan2
- TNFSF8 | c.115T>G p.F39V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV56343799; called by muse, mutect2
- TNP2 | c.262T>A p.S88T | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.901); catalogued as COSV57130007; called by muse, mutect2, varscan2
- TNXB | c.9893C>A p.P3298H (on ENST00000647633; = p.P3051H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64487436; called by muse, mutect2, varscan2
- TRERF1 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.08); catalogued as COSV61676936; called by muse, mutect2, varscan2
- TTN | c.74602G>C p.G24868R (on ENST00000591111; = p.G17444R on NM_003319.4) | Missense Mutation (SNP) | VAF 26/244 reads (11%) | PolyPhen benign (0.203); catalogued as COSV60288508; called by muse, mutect2, varscan2
- TTN | c.15789T>G p.N5263K (on ENST00000591111; = p.N4336K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/153 reads (42%) | PolyPhen possibly damaging (0.621); catalogued as COSV60288541; called by muse, mutect2, varscan2
- U2AF2 | c.1238A>G p.K413R | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1029612445, COSV58276034; called by muse, mutect2, varscan2
- UTP18 | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56584935; called by muse, mutect2, varscan2
- VWA8 | c.4281G>T p.R1427S | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1366482253, COSV64999702; called by muse, mutect2, varscan2
- WAC | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as COSV61569384; called by muse, mutect2, varscan2
- WNK1 | c.1021C>G p.R341G | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60028063; called by muse, mutect2
- XIRP2 | c.2965A>G p.T989A (on ENST00000628543; = p.T1164A on NM_152381.6) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs766920472, COSV54728483; called by muse, mutect2, varscan2
- ZC3H7B | c.2726G>A p.C909Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60964292; called by muse, mutect2, varscan2
- ZFP57 | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 121/219 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV65306845; called by muse, mutect2, varscan2
- ZNF354C | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV59609550; called by muse, mutect2, varscan2
- ZNF418 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 103/152 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV68676346; called by muse, mutect2, varscan2
- ANKEF1 | c.1541C>A p.S514* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- APMAP | c.1094_1120del p.L365_F373del | In Frame Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel
- BNIP5 | c.1415_1417delinsAAG p.P472_S473delinsQG | Missense Mutation (TNP) | VAF 14/90 reads (16%) | called by muse*, mutect2*, pindel, varscan2*
- CHRNB2 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- COL25A1 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.54A>T p.L18F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CSPP1 | c.2031G>T p.W677C (on ENST00000676605; = p.W636C on NM_024790.6) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMD6 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- GPR179 | c.5300G>C p.S1767T (on ENST00000621958; = p.S1766T on NM_001004334.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2
- HECTD4 | c.12247C>T p.Q4083* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- HMCN1 | c.6828del p.T2277Lfs*16 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- IER5 | c.743A>C p.Q248P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.211); called by muse, mutect2
- KHDRBS2 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- LAMA3 | c.5513A>T p.E1838V (on ENST00000313654 / NM_198129.4; = p.E229V on NM_000227.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2
- LSR | c.1157A>G p.E386G (on ENST00000361790; = p.E367G on NM_015925.6) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MRC1 | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 41/518 reads (8%) | called by muse, mutect2
- NRXN1 | c.755del p.G252Afs*17 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, pindel*, varscan2
- OR56B4 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- OSBPL3 | c.2240_2247del p.V747Afs*7 | Frame Shift Del (DEL) | VAF 82/228 reads (36%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.4513T>A p.W1505R | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2
- PCDHB5 | c.2273C>G p.S758* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- POM121 | c.2140T>C p.S714P (on ENST00000434423; = p.S449P on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP6R3 | c.2341G>T p.E781* (on ENST00000393800 / NM_001352375.2; = p.E701* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- RAD54B | c.2011_2023del p.Q671Ffs*44 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by pindel, varscan2
- SACS | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- TACC3 | c.2358_2365del p.S787Pfs*30 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- THAP9 | c.2014del p.W672Gfs*30 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- TRIM10 | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 107/173 reads (62%) | called by muse, mutect2, varscan2
- UPK1A | c.14_22del p.A5_A7del | In Frame Del (DEL) | VAF 27/146 reads (18%) | called by pindel, varscan2*
- WASHC2A | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- ACAD10 | c.1668C>T p.F556= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV58162010; called by muse, mutect2, varscan2
- ACO2 | c.2007G>C p.S669= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs757964630, COSV53444863; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM12 | c.1788C>G p.T596= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV64113259; called by muse, mutect2, varscan2
- AKAP10 | c.981G>A p.R327= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV56732752; called by muse, mutect2, varscan2
- ARHGAP32 | c.2556T>G p.S852= (on ENST00000310343 / NM_001378025.1; = p.S503= on NM_014715.4) | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV59854406; called by muse, mutect2, varscan2
- BOD1L1 | c.6471C>G p.S2157= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV50048117; called by muse, mutect2, varscan2
- C12orf50 | c.69C>A p.I23= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV53893140, COSV53895181, COSV53898217; called by muse, mutect2, varscan2
- C12orf60 | c.483C>G p.T161= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV57451089, COSV57453049, COSV99966813; called by muse, mutect2, varscan2
- C1orf158 | c.438C>G p.L146= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55347741; called by muse, mutect2, varscan2
- CAPN10 | c.612G>A p.E204= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV54379177; called by muse, mutect2, varscan2
- CHRNB2 | c.903C>T p.L301= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- CLCNKB | c.186G>C p.L62= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1163683248, COSV100990258, COSV65161687; called by muse, mutect2, varscan2
- COQ5 | c.762C>G p.L254= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV56020236, COSV99942333; called by muse, mutect2, varscan2
- DLG5 | c.3990C>A p.V1330= | Silent (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- DLGAP3 | c.915G>C p.S305= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs781101151, COSV52395341, COSV52396785, COSV52398573; called by muse, mutect2, varscan2
- DNAI1 | c.1587C>T p.S529= | Silent (SNP) | VAF 92/161 reads (57%) | catalogued as rs1204149839, COSV54284017; called by muse, mutect2, varscan2
- FAM160A2 | c.771C>T p.F257= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV56414123; called by muse, mutect2, varscan2
- FAM50B | c.627G>A p.V209= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV66655152; called by muse, mutect2, varscan2
- FCER1A | c.207C>T p.S69= | Silent (SNP) | VAF 75/118 reads (64%) | catalogued as COSV63668218; called by muse, mutect2, varscan2
- FGD4 | c.1053G>T p.R351= | Silent (SNP) | VAF 52/194 reads (27%) | catalogued as COSV56788517; called by muse, varscan2
- FLG | c.2142C>A p.L714= | Silent (SNP) | VAF 529/927 reads (57%) | catalogued as COSV64247307; called by muse, varscan2
- FRG1 | c.51C>A p.T17= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57006926; called by muse, mutect2, varscan2
- FSHR | c.1887T>C p.F629= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV58632643; called by muse, mutect2, varscan2
- GBA | c.864G>T p.L288= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV59170750; called by muse, mutect2, varscan2
- GLIS1 | c.147G>T p.L49= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56554930; called by muse, mutect2
- GPR32 | c.838C>T p.L280= | Silent (SNP) | VAF 85/113 reads (75%) | catalogued as rs765026775, COSV54515371; called by muse, mutect2, varscan2
- GSE1 | c.1554C>T p.F518= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- H2AZ2 | c.129C>T p.S43= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs1260946769; called by muse, mutect2
- HINFP | c.963C>T p.F321= | Silent (SNP) | VAF 62/102 reads (61%) | catalogued as COSV63432614, COSV63432909; called by muse, mutect2, varscan2
- HSF2 | c.195G>A p.L65= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as COSV63774457; called by muse, mutect2, varscan2
- IGSF9 | c.3522A>G p.E1174= (on ENST00000368094 / NM_001135050.2; = p.E1158= on NM_020789.4) | Silent (SNP) | VAF 101/177 reads (57%) | catalogued as COSV57423464; called by muse, mutect2, varscan2
- LCE1C | c.210T>A p.S70= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as COSV64219104; called by muse, mutect2
- LMBR1L | c.1281C>T p.F427= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs758602728, COSV57202835; called by muse, mutect2, varscan2
- LRIF1 | c.615G>T p.V205= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- LRTM2 | c.1056G>A p.L352= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV54566515; called by muse, mutect2
- MAGEC3 | c.564G>T p.V188= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as COSV71610181; called by muse, mutect2, varscan2
- MAT1A | c.246G>A p.V82= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1037690007, COSV64745650; called by muse, mutect2, varscan2
- MIOX | c.444C>T p.C148= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV53314444; called by muse, mutect2, varscan2
- NDUFB10 | c.228C>T p.I76= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as rs1230281267, COSV51910904; called by muse, mutect2, varscan2
- NOS2 | c.1083C>A p.G361= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV58226845; called by muse, mutect2, varscan2
- NR5A2 | c.981G>A p.Q327= (on ENST00000367362 / NM_205860.3; = p.Q281= on NM_003822.5) | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV52656583; called by muse, mutect2, varscan2
- NTRK1 | c.1521C>A p.R507= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV62328115; called by muse, mutect2
- NUDT1 | c.129G>C p.L43= (on ENST00000397048 / NM_198952.1; = p.L20= on NM_002452.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV54248141, COSV54248976; called by muse, mutect2, varscan2
- ORC4 | c.741G>A p.E247= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV51576542; called by muse, mutect2
- OXR1 | c.885A>G p.G295= (on ENST00000442977 / NM_001198532.1; = p.G294= on NM_018002.3) | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV56335057; called by muse, mutect2, varscan2
- PAQR4 | c.162G>C p.T54= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV51891468, COSV51892640; called by muse, mutect2, varscan2
- PCNX1 | c.5088C>G p.L1696= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV53100347; called by muse, mutect2, varscan2
- POLR2F | c.210G>T p.A70= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV68091961; called by muse, mutect2, varscan2
- PPP1R26 | c.2760C>T p.F920= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV63357121; called by muse, mutect2, varscan2
- PRH1 | c.387A>T p.P129= | Silent (SNP) | VAF 41/239 reads (17%) | catalogued as COSV101457466; called by muse, mutect2, varscan2
- PSME4 | c.5472C>T p.F1824= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV66367138; called by muse, mutect2, varscan2
- RIPK4 | c.1716G>A p.L572= (on ENST00000352483; = p.L524= on NM_020639.3) | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV60190390; called by muse, mutect2, varscan2
- RPL24 | c.429G>T p.V143= | Silent (SNP) | VAF 44/160 reads (28%) | called by muse, mutect2, varscan2
- SCAMP5 | c.36C>G p.P12= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as rs1222811745, COSV62644040; called by muse, varscan2
- SCAMP5 | c.63C>T p.F21= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV62644048; called by muse, varscan2
- SLC25A47 | c.108C>A p.I36= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV64162281; called by muse, mutect2, varscan2
- SNTA1 | c.420G>C p.G140= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV54130505; called by muse, mutect2
- SULT2B1 | c.774G>A p.T258= (on ENST00000201586 / NM_177973.2; = p.T243= on NM_004605.2) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs112884737, COSV52376347; called by muse, mutect2, varscan2
- TACR3 | c.1254A>G p.A418= | Silent (SNP) | VAF 14/221 reads (6%) | catalogued as rs1455183095, COSV59207330; called by muse, mutect2
- TCF20 | c.5094G>T p.S1698= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV59495315; called by muse, mutect2, varscan2
- TECPR2 | c.2442C>A p.L814= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as rs1227670267, COSV63973632, COSV63973642; called by muse, mutect2
- TIE1 | c.1152C>T p.S384= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV65251065; called by muse, mutect2, varscan2
- TMC7 | c.255C>A p.L85= | Silent (SNP) | VAF 49/70 reads (70%) | catalogued as COSV58587142; called by muse, mutect2, varscan2
- TMEM94 | c.2142A>G p.T714= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV58599277; called by muse, mutect2, varscan2
- TTLL7 | c.1215A>C p.S405= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV53087979; called by muse, mutect2, varscan2
- UNC79 | c.597A>G p.T199= (on ENST00000393151 / NM_001346218.2; = p.T22= on NM_020818.5) | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as rs763434779, COSV56406235; called by muse, mutect2, varscan2
- VAT1L | c.768G>T p.G256= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV56826797; called by muse, mutect2
- VEPH1 | c.2196C>T p.F732= | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as rs1367554940, COSV62881897; called by muse, mutect2, varscan2
- VILL | c.2259C>A p.A753= | Silent (SNP) | VAF 65/139 reads (47%) | catalogued as COSV52187517; called by muse, mutect2, varscan2
- VSTM1 | c.87C>T p.P29= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs1404540721, COSV58076463; called by muse, mutect2, varscan2
- WDR24 | c.2247C>G p.V749= (on ENST00000248142; = p.V619= on NM_032259.4) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV50203049; called by muse, mutect2, varscan2
- WLS | c.543C>T p.V181= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV52045915; called by muse, mutect2, varscan2
- XIRP2 | c.10026A>C p.I3342= (on ENST00000628543; = p.I3517= on NM_152381.6) | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV54728490; called by muse, mutect2
- ZC3H7B | c.2460C>T p.I820= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as COSV60964282; called by muse, mutect2, varscan2
- ZFP57 | c.1092C>A p.T364= | Silent (SNP) | VAF 121/217 reads (56%) | catalogued as COSV65306848; called by muse, mutect2, varscan2
- ZIM2 | c.1101C>G p.L367= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV55634935, COSV55644582, COSV99689073; called by muse, mutect2
- ZNF10 | c.924C>T p.L308= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV50214353; called by muse, mutect2, varscan2
- ZNF563 | c.633A>G p.L211= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as COSV53371939; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65497969 C>G | 5'Flank (SNP) | VAF 51/142 reads (36%) | called by muse, mutect2, varscan2
- POLR3D | chr8:22245021 G>A | 5'Flank (SNP) | VAF 35/103 reads (34%) | catalogued as rs566154595; called by muse, mutect2, varscan2
- SGK1 | chr6:134177729 del GATTACTTCTGGA | 5'Flank (DEL) | VAF 12/44 reads (27%) | called by pindel, varscan2
- TPM3 | chr1:154157663 G>C | 3'Flank (SNP) | VAF 21/283 reads (7%) | catalogued as COSV55137496, COSV55138862; called by muse, mutect2
